Somatic mutation profile of tumor specimen TCGA-D5-6534-01A (aliquot TCGA-D5-6534-01A-21D-1924-10) from TCGA case TCGA-D5-6534, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.4 years (22,778 days).
Specimen TCGA-D5-6534-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f26320e1-bce6-4ad5-ae9c-9fbdb0412f39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6534-10A (Blood Derived Normal), aliquot TCGA-D5-6534-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd43c47d-0bde-406c-ae96-7268489f362e

The open-access MAF lists 164 somatic variants for this specimen: 131 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 32, Nonsense Mutation 7, Splice Site 6, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLM | c.2407-1G>A p.X803_splice | Splice Site (SNP) | VAF 34/163 reads (21%) | catalogued as rs1555420871, COSV100757286; ClinVar: likely pathogenic; called by muse, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RYR2 | c.12298G>A p.V4100I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758785338, COSV63665946; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3795C>A p.F1265L (on ENST00000272895 / NM_173076.3; = p.F947L on NM_015657.3) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV55969992, COSV55970062; called by muse, mutect2
- ABCA4 | c.2742C>T p.H914= | Splice Region (SNP) | VAF 74/491 reads (15%) | catalogued as rs1362746093, COSV100933181; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- ABCA8 | c.3005G>T p.S1002I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs567388528, COSV99286530; called by muse, mutect2, varscan2
- ABHD11 | c.531T>A p.F177L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1388613502, COSV56106231; called by muse, mutect2
- ACAN | c.2528C>A p.T843K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as COSV61366305; called by muse, mutect2, varscan2
- ADAMTS19 | c.1325C>A p.T442K | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV50776032; called by muse, mutect2, varscan2
- ADGRA3 | c.2379G>C p.K793N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51561296, COSV51566600; called by muse, mutect2, varscan2
- AFF3 | c.3322G>A p.G1108R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs542558981, COSV57866109; called by mutect2, varscan2
- AGTPBP1 | c.2465A>C p.K822T (on ENST00000357081 / NM_001330701.2; = p.K782T on NM_015239.2) | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV61275395; called by muse, mutect2, varscan2
- AL441992.2 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs767222724, COSV56915878; called by muse, mutect2, varscan2
- ALDOB | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66398402; called by muse, mutect2, varscan2
- ALPP | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV67397377; called by muse, mutect2, varscan2
- ANP32B | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | catalogued as COSV59586594; called by muse, mutect2, varscan2
- ARHGAP30 | c.2351A>C p.E784A | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV63518318; called by muse, mutect2, varscan2
- ATP10D | c.3374T>G p.V1125G | Missense Mutation (SNP) | VAF 60/425 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99905973; called by muse, mutect2, varscan2
- ATP8B1 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52178648; called by muse, mutect2, varscan2
- BEST2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs768418645, COSV50359401; called by muse, mutect2, varscan2
- BRWD3 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV64751984; called by muse, mutect2, varscan2
- C8B | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV64778863; called by muse, mutect2
- CACNA1B | c.4259A>T p.Q1420L | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53140946; called by muse, mutect2, varscan2
- CACNA1S | c.5407G>T p.D1803Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100754892, COSV100755227; called by muse, mutect2, varscan2
- CCDC62 | c.230-1G>C p.X77_splice | Splice Site (SNP) | VAF 18/108 reads (17%) | catalogued as COSV53432272, COSV53436142; called by muse, mutect2
- CHST2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs1176725355, COSV58886612; called by muse, mutect2, varscan2
- CHUK | c.1231+1G>T p.X411_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV64918488; called by muse, mutect2, varscan2
- CILP | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs149286218; called by mutect2, varscan2
- COL24A1 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538248306, COSV65301938; called by muse, mutect2, varscan2
- COL24A1 | c.1428G>C p.E476D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV100993792; called by mutect2, varscan2
- CSNK1E | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV100725069; called by muse, mutect2
- CTNNA1 | c.2577G>A p.W859* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | catalogued as COSV100243128; called by muse, mutect2, varscan2
- DECR1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs781613500, COSV55169886; called by mutect2, varscan2
- DNER | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs761933088, COSV59172750, COSV99080081; called by muse, mutect2, varscan2
- DSCAM | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV68650125; called by muse, mutect2, varscan2
- DSEL | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV59493615; called by muse, mutect2, varscan2
- DUSP9 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV61438265; called by muse, mutect2, varscan2
- ELMO1 | c.701+2T>G p.X234_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100165482; called by muse, mutect2, varscan2
- EMCN | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV56462289; called by muse, mutect2, varscan2
- ERBB3 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as rs772747085, COSV57258607; called by muse, mutect2, varscan2
- EXD1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs186855358, COSV59255697; called by muse, mutect2, varscan2
- FOXO4 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs1343873555, COSV58576092; called by muse, mutect2, varscan2
- GAB3 | c.1733G>T p.W578L | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65820425; called by muse, mutect2, varscan2
- GABRA2 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62917898; called by muse, mutect2, varscan2
- GABRR1 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 28/164 reads (17%) | catalogued as COSV65620155, COSV65620270; called by muse, mutect2, varscan2
- GJA3 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV53835580; called by muse, mutect2, varscan2
- GPC6 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.577); catalogued as rs775575495, COSV65527089; called by muse, mutect2, varscan2
- GPR141 | c.690dup p.I231Yfs*15 | Frame Shift Ins (INS) | VAF 30/226 reads (13%) | catalogued as rs761658492; called by mutect2, pindel, varscan2
- HMCN1 | c.6646C>A p.L2216M | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99633442; called by muse, mutect2, varscan2
- HNRNPD | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as rs866367819, COSV58314514; called by muse, mutect2, varscan2
- IFIT2 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as rs773031617, COSV51080140; called by muse, mutect2, varscan2
- INO80D | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.864); catalogued as COSV68959717; called by muse, mutect2, varscan2
- ISM2 | c.313T>G p.L105V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV53636354; called by muse, mutect2, varscan2
- ITGA7 | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV57698899; called by muse, mutect2, varscan2
- KANK4 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 17/129 reads (13%) | catalogued as COSV62988391; called by muse, mutect2, varscan2
- KCNA6 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs781656226, COSV54974189, COSV54975172; called by muse, mutect2, varscan2
- KIAA1522 | c.467G>C p.R156P (on ENST00000373480 / NM_001198972.2; = p.R215P on NM_020888.3) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs74067513, COSV53864067, COSV53866772; called by muse, mutect2, varscan2
- KRT35 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs200010064; called by muse, mutect2, varscan2
- LACRT | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV57688551; called by muse, mutect2, varscan2
- LRCH1 | c.1092C>A p.D364E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV60851296; called by muse, mutect2, varscan2
- MCF2 | c.2256C>G p.Y752* | Nonsense Mutation (SNP) | VAF 33/170 reads (19%) | catalogued as COSV58491637; called by muse, mutect2, varscan2
- MLH3 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as rs569011240, COSV53157409, COSV53157589, COSV99469511; called by muse, mutect2, varscan2
- MTTP | c.2402T>G p.L801R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99645455; called by mutect2, varscan2
- MYO18A | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV62866100; called by muse, mutect2, varscan2
- NEXMIF | c.579G>C p.M193I | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV50032912, COSV99281438; called by muse, mutect2, varscan2
- NIBAN1 | c.1109A>T p.E370V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62286854; called by muse, mutect2, varscan2
- NLGN4X | c.2318T>G p.L773R | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV52011412, COSV99322018; called by muse, mutect2, varscan2
- NLRP8 | c.1319A>C p.E440A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as COSV52591749; called by muse, mutect2, varscan2
- NOXA1 | c.699-1G>T p.X233_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58163088; called by muse, mutect2, varscan2
- NPFFR2 | c.1326C>A p.F442L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100441085; called by muse, mutect2, varscan2
- OAS1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs148820389; called by muse, mutect2, varscan2
- OR14I1 | c.285T>G p.C95W | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61200481; called by muse, mutect2, varscan2
- OR2J3 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV65849020, COSV65849371; called by muse, mutect2, varscan2
- OR2T10 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV57896677, COSV57897738; called by muse, mutect2, varscan2
- OR8A1 | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52509515; called by muse, mutect2, varscan2
- OR9G1 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100380500; called by muse, mutect2
- PAMR1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs369548670; called by muse, mutect2, varscan2
- PCCA | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66196644; called by muse, mutect2, varscan2
- PCDHGA5 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV54002531; called by muse, mutect2, varscan2
- PCLO | c.6086T>C p.I2029T | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs541483075, COSV61655752; called by muse, mutect2, varscan2
- PDE1B | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373781937; called by muse, mutect2, varscan2
- PGLYRP2 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV52996494; called by muse, mutect2, varscan2
- PKHD1 | c.8834G>A p.R2945H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1208940193, COSV61889464; called by muse, mutect2, varscan2
- PPIE | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs764879686, COSV60970803; called by muse, mutect2, varscan2
- PPP1R3C | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs182503852, COSV53288114; called by muse, mutect2, varscan2
- PPP1R42 | c.42T>A p.N14K | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV61208904; called by muse, mutect2, varscan2
- PRKD1 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59579363; called by muse, mutect2, varscan2
- PSAP | c.1259A>T p.D420V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV56469643; called by muse, mutect2, varscan2
- PSAP | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56480975; called by muse, mutect2, varscan2
- RBM12B | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV66968346; called by muse, mutect2, varscan2
- RHBG | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV99659915; called by muse, mutect2, varscan2
- RIMBP2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs370977982, COSV99899668; called by muse, mutect2, varscan2
- ROBO3 | c.2201T>A p.L734H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67302109; called by muse, mutect2, varscan2
- RYR3 | c.12356C>T p.S4119F (on ENST00000389232; = p.S4120F on NM_001036.6) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101213538; called by muse, mutect2, varscan2
- S1PR4 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55741064; called by muse, mutect2, varscan2
- SCN11A | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374524879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEPHS1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV59259975; called by muse, mutect2, varscan2
- SERPINB4 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 67/493 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as rs1395622867, COSV61985546; called by muse, mutect2, varscan2
- SI | c.4280G>A p.R1427K | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV100016935, COSV52302260; called by muse, mutect2, varscan2
- SLC25A2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1554296137, COSV53404197; called by muse, mutect2, varscan2
- SLC5A6 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1399464185, COSV60160785; called by muse, mutect2, varscan2
- SLITRK1 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs886050335, COSV65676951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.4051G>A p.D1351N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs1318154109, COSV60795432; called by muse, mutect2, varscan2
- SNTB1 | c.1511A>C p.K504T | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV67328231; called by muse, mutect2, varscan2
- SYCP2 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100698384, COSV100698447; called by muse, mutect2, varscan2
- SYNE1 | c.11895C>A p.H3965Q | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99573803; called by muse, mutect2, varscan2
- TASOR2 | c.3860C>A p.T1287K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV60168900; called by muse, mutect2, varscan2
- TBX3 | c.942-1G>T p.X314_splice (on ENST00000257566 / NM_016569.4; = p.X294_splice on NM_005996.4) | Splice Site (SNP) | VAF 9/70 reads (13%) | catalogued as COSV57469844, COSV57472904; called by muse, mutect2, varscan2
- TCHH | c.4745G>A p.R1582H | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV64272925; called by muse, mutect2, varscan2
- TFDP2 | c.368A>C p.K123T (on ENST00000489671 / NM_001178139.2; = p.K62T on NM_006286.5) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV57710098; called by muse, mutect2, varscan2
- TGM6 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs992743590, COSV52482846; called by muse, mutect2, varscan2
- TIGD5 | c.318_319insCAA p.G106_G107insQ | In Frame Ins (INS) | VAF 9/56 reads (16%) | catalogued as COSV57821899; called by mutect2, pindel, varscan2
- TMC4 | c.1480A>C p.T494P (on ENST00000617472 / NM_001145303.3; = p.T488P on NM_144686.4) | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV55826431, COSV55828312; called by muse, mutect2, varscan2
- TMF1 | c.1755G>T p.E585D | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV68375087; called by muse, mutect2
- TPSG1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV52357007; called by muse, mutect2, varscan2
- TRMT1L | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as COSV62257940; called by muse, mutect2, varscan2
- TRPV6 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273435875, COSV63893001; called by muse, mutect2
- TUBA3C | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1354838240, COSV67139009, COSV67139869; called by muse, mutect2
- UBE2E2 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV100233507; called by muse, mutect2
- UQCC1 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62903188; called by muse, mutect2, varscan2
- VWF | c.5355G>A p.M1785I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54629795; called by muse, mutect2, varscan2
- XKRX | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV60708901; called by muse, mutect2, varscan2
- ZCRB1 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs761704622, COSV99861195, COSV99861336; called by muse, mutect2
- ZNF493 | c.830A>C p.H277P | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV62751319; called by muse, mutect2, varscan2
- ZNF493 | c.831C>A p.H277Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV62751327; called by muse, mutect2, varscan2
- ZNF560 | c.342T>G p.S114R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV56870363; called by muse, mutect2, varscan2
- ZSCAN1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs148253808; called by muse, mutect2, varscan2
- ZSWIM2 | c.837C>A p.N279K | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1294801291, COSV99720410; called by muse, mutect2, varscan2
- GABRQ | c.269_270del p.Y90Cfs*5 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- TP53 | c.608_609del p.V203Gfs*5 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by pindel, varscan2
- TRIM60 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.296); called by muse, mutect2
- ADAMTS16 | c.3633C>T p.Y1211= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs367839151, COSV56979580; called by muse, mutect2, varscan2
- ALG13 | c.3267G>T p.V1089= | Silent (SNP) | VAF 35/232 reads (15%) | catalogued as COSV52643037; called by muse, mutect2, varscan2
- BCKDHB | c.970C>A p.R324= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as CM970165, COSV57516388, COSV57516941; called by muse, mutect2, varscan2
- CCDC33 | c.408C>G p.P136= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100351744, COSV58354904; called by muse, mutect2, varscan2
- CRMP1 | c.183C>T p.N61= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs752770907, COSV61481635; called by muse, mutect2, varscan2
- DCP1B | c.1563G>A p.P521= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs370457514; called by mutect2, varscan2
- ETV1 | c.411C>G p.P137= | Silent (SNP) | VAF 37/234 reads (16%) | catalogued as COSV54148561; called by muse, mutect2, varscan2
- GDF5 | c.759G>A p.A253= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs749839438, COSV65502778; called by muse, mutect2
- GDF6 | c.1218G>A p.L406= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as COSV54626848; called by muse, mutect2, varscan2
- GIMAP7 | c.33C>T p.I11= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs142236871, COSV57959703; called by muse, mutect2, varscan2
- GRM1 | c.189C>T p.P63= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV51231830; called by muse, mutect2, varscan2
- IGKV2D-29 | c.102C>G p.T34= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as COSV101534393; called by muse, mutect2, varscan2
- ISM2 | c.312G>A p.P104= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs757019613, COSV53636366; called by muse, mutect2, varscan2
- KCNQ3 | c.642T>C p.A214= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101196293; called by muse, mutect2
- KRTAP19-1 | c.36C>A p.G12= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as COSV66861480; called by muse, mutect2, varscan2
- MAGEE1 | c.1746C>G p.G582= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV63911564; called by muse, mutect2, varscan2
- MYH7B | c.249C>T p.D83= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs928556451, COSV53417407; called by muse, mutect2
- MYL7 | c.351C>T p.S117= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs144625240, COSV56268593; called by mutect2, varscan2
- MYOM2 | c.2583T>G p.T861= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV50749147; called by muse, mutect2, varscan2
- NCKAP1L | c.189C>G p.P63= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV53210526, COSV99515432; called by muse, mutect2, varscan2
- NEB | c.4251C>T p.D1417= | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as rs550832252, COSV50850864; ClinVar: likely benign; called by muse, mutect2
- NOTCH1 | c.3490C>T p.L1164= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs748055658, COSV53077686; called by muse, mutect2, varscan2
- PDE6A | c.45G>A p.S15= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs146811139; called by muse, mutect2, varscan2
- PLXDC2 | c.789T>A p.P263= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV65907188; called by muse, mutect2, varscan2
- RASGRF1 | c.3255C>T p.H1085= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV60213145; called by muse, mutect2, varscan2
- SLC5A4 | c.1185C>T p.T395= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1385794315, COSV56672836; called by muse, mutect2, varscan2
- SLC9A3 | c.1428C>T p.N476= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs202060130; called by mutect2, varscan2
- SLC9A9 | c.1443C>A p.T481= | Silent (SNP) | VAF 10/175 reads (6%) | catalogued as COSV57250959; called by muse, mutect2
- SUV39H1 | c.57G>A p.L19= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV61921160; called by muse, mutect2, varscan2
- TPO | c.594C>T p.N198= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs375152400; called by muse, mutect2, varscan2
- TRPS1 | c.3063G>T p.L1021= (on ENST00000220888 / NM_001330599.2; = p.L1034= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/218 reads (16%) | catalogued as rs202057117, COSV55255146; called by muse, mutect2, varscan2
- ZNF440 | c.249T>G p.T83= | Silent (SNP) | VAF 39/198 reads (20%) | catalogued as COSV58371949; called by muse, mutect2, varscan2
- VPS11 | chr11:119067932 T>C | 5'Flank (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100333918; called by muse, mutect2, varscan2
